CPTAC case C3L-05261 — Skin — Nevi and Melanomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Nevi and Melanomas; Primary site: Skin. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/6f6e7593-fc84-48d8-afb6-4f8dfc025c6d

Demographics
Sex at birth: male; Race: white; Year of birth: 1979; Vital status: Dead; Days to death: 1,294 days (3.5 years); Year of death: 2023; Cause of death: Cancer Related; Country of birth: Serbia.

Diagnoses (1)
1. Malignant melanoma, NOS: ICD-O-3 morphology code: 8720/3; Tissue or organ of origin: Skin, NOS; Site of resection or biopsy: Skin of trunk; Age at diagnosis: 40.5 years (14,788 days); Year of diagnosis: 2019; AJCC staging edition: 8th; AJCC clinical M: M0; AJCC pathologic T: T4b; AJCC pathologic N: N3c; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIIC; Residual disease: R0; Last known disease status: With tumor; Days to last known disease status: 1,294 days (3.5 years); Progression or recurrence: yes; Days to recurrence: 632 days (1.7 years); Days to last follow up: 1,294 days (3.5 years); Clark level: IV; Tumor focality: Unifocal; Ulceration indicator: Yes.
   Pathology details: Breslow thickness category: >4.0 mm; Greatest tumor dimension: 5.5 cm; Lymph node involvement: Negative; Lymph nodes positive: 0; Lymphatic invasion present: Yes; Margin status: Uninvolved; Perineural invasion present: No; Vascular invasion present: Yes.
   Chemotherapy — whether it was given is not recorded by GDC; Treatment outcome: Persistent Disease.
   Immunotherapy (Including Vaccines) — whether it was given is not recorded by GDC; Treatment outcome: Persistent Disease.

Follow-up (4 entries)
- Days to follow up: 240 days; Disease response: With Tumor; Karnofsky performance status: 90; ECOG performance status: 1.
- Days to follow up: 653 days (1.8 years); Disease response: With Tumor.
- Days to follow up: 1,028 days (2.8 years); Disease response: With Tumor; Karnofsky performance status: 80; ECOG performance status: 1.
- Days to follow up: 1,294 days (3.5 years); Disease response: With Tumor; Karnofsky performance status: 0; ECOG performance status: 5.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Smoker; Pack years smoked: 40; Cigarettes per day: 40; Tobacco smoking onset year: 1999; Alcohol history: Yes; Alcohol intensity: Not Heavy Drinker; Exposure duration years: 23.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3L-05261-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Trunk; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -7 days; Initial weight: 46 mg; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-05261-23: Section location: Trunk; Percent tumor nuclei: 70; Percent necrosis: 0.
- Sample C3L-05261-04: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Trunk; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -7 days; Initial weight: 116 mg; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-05261-24: Section location: Trunk; Percent tumor nuclei: 80; Percent necrosis: 0.
- Sample C3L-05261-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: -7 days; Method of sample procurement: Blood Draw.
